Somatic mutation profile of cancer-model specimen HCM-BROD-0344-C25-85A (3D Organoid, passage 4; aliquot HCM-BROD-0344-C25-85A-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0344-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 73.1 years (26,701 days).
Specimen HCM-BROD-0344-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9808d16-da49-4a6c-aeec-a604d21ef98c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0344-C25-10B (Blood Derived Normal), aliquot HCM-BROD-0344-C25-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c19bb5c-24d5-460f-a24b-a1823d1d7d68

The open-access MAF lists 98 somatic variants for this specimen: 73 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 66, Silent 25, Frame Shift Ins 3, In Frame Ins 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 152/263 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 302/302 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.2525G>A p.R842Q (on ENST00000326195 / NM_001025091.2; = p.R804Q on NM_001090.3) | Missense Mutation (SNP) | VAF 123/432 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as rs375225504; called by muse, mutect2, varscan2
- ACVR1B | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 343/345 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57780952; called by muse, mutect2, varscan2
- AFDN | c.2226G>A p.M742I | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV60052839; called by muse, mutect2, varscan2
- C19orf25 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 382/384 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1405817209; called by muse, mutect2, varscan2
- CHN1 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV55033641; called by muse, mutect2, varscan2
- CNGB1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 142/426 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768575862, COSV51905312; called by muse, mutect2, varscan2
- CREB5 | c.77G>A p.R26H (on ENST00000357727 / NM_182898.4; = p.R19H on NM_004904.3) | Missense Mutation (SNP) | VAF 164/284 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs765299339; called by muse, mutect2, varscan2
- DCTN1 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 227/511 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1443384895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK8 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 119/236 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV66622518; called by muse, mutect2, varscan2
- EFCAB5 | c.3281G>A p.R1094H | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as rs760738148, COSV57931965; called by muse, mutect2, varscan2
- EPHA8 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 240/341 reads (70%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs755476945; called by muse, mutect2, varscan2
- GC | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs1401572719; called by muse, mutect2, varscan2
- INPP5J | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs370872946; called by muse, mutect2, varscan2
- ITIH2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs375764473; called by muse, mutect2, varscan2
- KLK15 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 222/327 reads (68%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.892); catalogued as rs374766999; called by muse, varscan2
- LRRN2 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 341/499 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1434466332; called by muse, mutect2, varscan2
- LTBP3 | c.3745del p.R1249Afs*13 (on ENST00000301873 / NM_001130144.3; = p.R1202Afs*13 on NM_021070.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 138/347 reads (40%) | catalogued as COSV54212088; called by mutect2, pindel, varscan2
- MEGF6 | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 118/464 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as rs867794997; called by muse, mutect2, varscan2
- NT5DC2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs764118430, COSV58742656; called by muse, mutect2, varscan2
- PCDHGA8 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53907990; called by muse, mutect2, varscan2
- PPFIA4 | c.1895C>T p.T632M (on ENST00000447715; = p.T633M on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/571 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs565283433, COSV55314310; called by muse, mutect2, varscan2
- PPL | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 149/487 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746629139; called by muse, mutect2
- PTPN13 | c.4567C>T p.P1523S (on ENST00000411767 / NM_080683.3; = p.P1504S on NM_006264.3) | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.178); catalogued as rs1021425298, COSV100363816; called by muse, mutect2, varscan2
- QRFPR | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 361/361 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57676932; called by muse, mutect2, varscan2
- RIMS1 | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1172432347, COSV53440535; called by muse, mutect2, varscan2
- SLC30A10 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 85/613 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV63072796; called by muse, mutect2, varscan2
- SPTA1 | c.5377C>T p.R1793W | Missense Mutation (SNP) | VAF 144/463 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375618954; called by muse, mutect2, varscan2
- ST6GAL2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 283/603 reads (47%) | PolyPhen benign (0); catalogued as rs781338462, COSV64525788; called by muse, mutect2, varscan2
- TNP2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 35/686 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV57129916; called by muse, mutect2
- TRPC1 | c.2345G>A p.R782Q (on ENST00000476941 / NM_001251845.2; = p.R748Q on NM_003304.4) | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs759693044; called by muse, mutect2, varscan2
- TSPAN1 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs372580265; called by muse, mutect2, varscan2
- VEGFC | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 326/329 reads (99%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs748396345; called by muse, varscan2
- WASF3 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 319/453 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.237); catalogued as rs748043020, COSV58971250; called by muse, mutect2, varscan2
- ADGRL2 | c.1625T>C p.L542P | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ANKRD12 | c.1189C>A p.H397N | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10B | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 107/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8A2 | c.2352G>C p.L784F | Missense Mutation (SNP) | VAF 129/386 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BAG6 | c.2716_2718dup p.L907dup (on ENST00000676571; = p.L860dup on NM_080702.3 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 127/455 reads (28%) | called by mutect2, pindel, varscan2
- CCDC18 | c.4129T>G p.L1377V | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- COL12A1 | c.5044G>T p.V1682L | Missense Mutation (SNP) | VAF 120/392 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CPA2 | c.963dup p.K322Qfs*4 | Frame Shift Ins (INS) | VAF 72/185 reads (39%) | called by mutect2, pindel, varscan2
- CPT2 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 144/449 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CRB2 | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 378/378 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, varscan2
- DCN | c.518T>A p.L173Q | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DCN | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ERBB4 | c.1517T>C p.L506P | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- ERI2 | c.1266C>G p.N422K | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- FAM193A | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- GANC | c.1883dup p.L629Afs*76 | Frame Shift Ins (INS) | VAF 103/259 reads (40%) | called by mutect2, pindel, varscan2
- GRIA2 | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 158/160 reads (99%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN3A | c.1031A>T p.Q344L | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- IRX1 | c.1136T>C p.F379S | Missense Mutation (SNP) | VAF 558/866 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRK2 | c.1179C>A p.G393= | Splice Region (SNP) | VAF 122/374 reads (33%) | called by muse, mutect2, varscan2
- MAP3K3 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAZ | c.858_859insT p.A287Cfs*44 | Frame Shift Ins (INS) | VAF 175/650 reads (27%) | called by mutect2, pindel, varscan2
- NDST2 | c.583T>G p.L195V | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- PABPC4L | c.938T>A p.F313Y | Missense Mutation (SNP) | VAF 113/207 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PCLO | c.9191C>A p.S3064Y | Missense Mutation (SNP) | VAF 149/407 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGLYRP2 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 24/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHLDB3 | c.1873A>G p.I625V | Missense Mutation (SNP) | VAF 124/413 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLEKHA5 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SENP2 | c.1550A>C p.K517T | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TEX26 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 140/388 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TEX44 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 252/533 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM218 | c.27_56del p.A10_W19del | In Frame Del (DEL) | VAF 96/319 reads (30%) | called by mutect2, pindel, varscan2
- TMEM255B | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 164/433 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TOGARAM1 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- TSPYL1 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 201/596 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.49861G>A p.D16621N (on ENST00000591111; = p.D9197N on NM_003319.4) | Missense Mutation (SNP) | VAF 194/330 reads (59%) | PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- UBE2L5 | c.166A>C p.N56H | Missense Mutation (SNP) | VAF 38/548 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2
- ZFHX4 | c.6316T>C p.S2106P | Missense Mutation (SNP) | VAF 155/597 reads (26%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCB1 | c.2751A>G p.E917= | Silent (SNP) | VAF 161/356 reads (45%) | called by muse, mutect2, varscan2
- AFAP1 | c.1581G>A p.G527= | Silent (SNP) | VAF 307/308 reads (100%) | called by muse, mutect2, varscan2
- ALKAL1 | c.288A>G p.R96= | Silent (SNP) | VAF 197/413 reads (48%) | called by muse, mutect2, varscan2
- ARID1B | c.5496C>T p.R1832= | Silent (SNP) | VAF 96/326 reads (29%) | called by muse, mutect2, varscan2
- C2CD5 | c.1443A>G p.T481= | Silent (SNP) | VAF 123/420 reads (29%) | called by muse, mutect2, varscan2
- CD5 | c.438G>A p.P146= | Silent (SNP) | VAF 126/299 reads (42%) | catalogued as rs753011554, COSV61717797, COSV61719350; called by muse, varscan2
- CDH13 | c.1350C>T p.L450= | Silent (SNP) | VAF 145/466 reads (31%) | catalogued as rs370031597; called by muse, mutect2, varscan2
- CLSTN2 | c.102G>A p.A34= | Silent (SNP) | VAF 110/398 reads (28%) | catalogued as rs554776795; called by muse, mutect2, varscan2
- DST | c.10053G>A p.L3351= | Silent (SNP) | VAF 98/277 reads (35%) | called by muse, mutect2, varscan2
- IRX2 | c.948G>A p.T316= | Silent (SNP) | VAF 541/806 reads (67%) | catalogued as rs1393206460; called by muse, mutect2, varscan2
- JPH2 | c.1140G>A p.A380= | Silent (SNP) | VAF 163/649 reads (25%) | catalogued as rs780588148, COSV65905219; called by muse, mutect2, varscan2
- KPNB1 | c.1887G>A p.L629= | Silent (SNP) | VAF 95/308 reads (31%) | catalogued as rs749505079; called by muse, mutect2, varscan2
- MARS1 | c.123G>A p.P41= | Silent (SNP) | VAF 97/301 reads (32%) | called by muse, mutect2, varscan2
- NOC3L | c.1047G>C p.L349= | Silent (SNP) | VAF 178/350 reads (51%) | catalogued as rs1266919544; called by muse, mutect2, varscan2
- OR7C2 | c.924G>A p.T308= | Silent (SNP) | VAF 168/169 reads (99%) | catalogued as rs1204583566; called by muse, mutect2, varscan2
- PCDHA5 | c.1860G>A p.P620= | Silent (SNP) | VAF 131/279 reads (47%) | catalogued as rs782817959; called by muse, mutect2, varscan2
- PLEC | c.5508G>A p.Q1836= (on ENST00000322810 / NM_201380.4; = p.Q1726= on NM_000445.5) | Silent (SNP) | VAF 308/1278 reads (24%) | called by muse, mutect2, varscan2
- RNF213 | c.4611C>T p.A1537= | Silent (SNP) | VAF 29/473 reads (6%) | called by muse, mutect2
- RYR3 | c.3990C>T p.Y1330= | Silent (SNP) | VAF 147/147 reads (100%) | catalogued as rs531084938, COSV66801553; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINE1 | c.354C>T p.D118= | Silent (SNP) | VAF 207/491 reads (42%) | catalogued as rs1419367601, COSV56168954; called by muse, mutect2, varscan2
- SLC32A1 | c.1359C>T p.F453= | Silent (SNP) | VAF 218/935 reads (23%) | catalogued as COSV54145628; called by muse, mutect2, varscan2
- SPEF2 | c.5468G>A p.*1823= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as rs1348681789; called by muse, mutect2, varscan2
- TRIM58 | c.15G>A p.P5= | Silent (SNP) | VAF 124/256 reads (48%) | catalogued as rs745500964; called by muse, mutect2, varscan2
- TXNDC15 | c.462G>A p.A154= | Silent (SNP) | VAF 157/300 reads (52%) | catalogued as rs143292161, COSV100613640; called by muse, mutect2, varscan2
- ZNF518B | c.2154C>T p.G718= | Silent (SNP) | VAF 112/244 reads (46%) | called by muse, mutect2, varscan2
